Somatic mutation profile of cancer-model specimen HCM-SANG-0311-C15-85A (3D Organoid; aliquot HCM-SANG-0311-C15-85A-01D-A79N-36), derived from the primary tumor of HCMI case HCM-SANG-0311-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: GX.
Specimen HCM-SANG-0311-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd6bb682-c7a1-4ba6-a55f-5a4ce8a2fff0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0311-C15-10B (Blood Derived Normal), aliquot HCM-SANG-0311-C15-10B-01D-A79N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc2d1be1-7202-4482-b93a-fc56044b8c04

The open-access MAF lists 178 somatic variants for this specimen: 128 protein-altering or splice-affecting, 42 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 42, Frame Shift Del 8, Nonsense Mutation 7, Intron 5, Frame Shift Ins 3, Splice Site 2, In Frame Del 2, RNA 1, 3'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 123/299 reads (41%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 186/186 reads (100%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ARID1A | c.4005-1G>A p.X1335_splice | Splice Site (SNP) | VAF 142/247 reads (57%) | catalogued as COSV100254233; called by muse, mutect2, varscan2
- CENPF | c.5212A>G p.K1738E | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV100871842; called by muse, mutect2, varscan2
- CLSTN2 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 180/379 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs142015908; called by muse, mutect2, varscan2
- COL11A2 | c.3181C>T p.R1061* (on ENST00000341947 / NM_080680.3; = p.R954* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 247/488 reads (51%) | catalogued as rs776576899, COSV100554440; called by muse, mutect2, varscan2
- COL6A3 | c.4678G>A p.A1560T | Missense Mutation (SNP) | VAF 252/514 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs371631320; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.9839G>T p.S3280I (on ENST00000297405 / NM_001363185.1; = p.S3111I on NM_052900.3) | Missense Mutation (SNP) | VAF 120/210 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV52292486; called by muse, mutect2, varscan2
- CSTF1 | c.915C>A p.D305E | Missense Mutation (SNP) | VAF 207/612 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV53857825; called by muse, mutect2, varscan2
- DOCK4 | c.2356T>A p.L786M | Missense Mutation (SNP) | VAF 96/321 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.234); catalogued as COSV101448015; called by muse, mutect2, varscan2
- DPYSL4 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 124/287 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs757758956; called by muse, mutect2, varscan2
- EN1 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 216/427 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs372072112; called by muse, mutect2, varscan2
- EPS8L2 | c.1089C>G p.I363M | Missense Mutation (SNP) | VAF 42/365 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as COSV100585287; called by muse, varscan2
- FUT8 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs762317080; called by muse, mutect2, varscan2
- FZD7 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 281/617 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as rs201191053; called by muse, mutect2, varscan2
- GASK1A | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 284/531 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs760589443, COSV56181468; called by muse, mutect2, varscan2
- GLI3 | c.2041A>G p.N681D | Missense Mutation (SNP) | VAF 226/447 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1293732858; called by muse, mutect2, varscan2
- GMNC | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 70/334 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1349914319; called by muse, mutect2, varscan2
- GRWD1 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281517559, COSV53520518; called by muse, mutect2, varscan2
- HELZ2 | c.2104C>T p.R702W (on ENST00000467148 / NM_001037335.2; = p.R133W on NM_033405.3) | Missense Mutation (SNP) | VAF 291/622 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs771861586; called by muse, mutect2, varscan2
- IQSEC3 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 154/626 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1555083269; called by muse, mutect2, varscan2
- LRIT2 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 249/521 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as rs776287901, COSV60563108; called by muse, mutect2, varscan2
- LRRN1 | c.1650G>T p.M550I | Missense Mutation (SNP) | VAF 41/377 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV60014754; called by muse, mutect2, varscan2
- MAPK3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 109/434 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1315743155; called by muse, mutect2, varscan2
- MCF2L2 | c.2591G>T p.R864L | Missense Mutation (SNP) | VAF 152/331 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs143903251, COSV61049587; called by muse, mutect2, varscan2
- MCF2L2 | c.2203T>A p.F735I | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61053209; called by muse, mutect2, varscan2
- MGAT3 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 93/330 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.769); catalogued as COSV100361953; called by muse, mutect2, varscan2
- MNDA | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs914856154; called by muse, mutect2, varscan2
- MPI | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 190/384 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760519827; called by muse, mutect2, varscan2
- NHSL1 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 268/539 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs763185214; called by muse, mutect2, varscan2
- OBSL1 | c.2938A>G p.T980A | Missense Mutation (SNP) | VAF 158/337 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs777862393, COSV54705727; called by muse, mutect2, varscan2
- OR4C46 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.053); catalogued as COSV60219067; called by muse, mutect2
- OSBPL7 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 162/283 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338064257; called by muse, varscan2
- P2RX5 | c.435C>T p.N145= | Splice Region (SNP) | VAF 213/213 reads (100%) | catalogued as rs576550203; called by muse, mutect2, varscan2
- PKD1L1 | c.848C>G p.A283G | Missense Mutation (SNP) | VAF 103/408 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV56970246; called by muse, mutect2, varscan2
- POTEJ | c.1915T>C p.Y639H | Missense Mutation (SNP) | VAF 203/685 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as rs1438309496; called by muse, mutect2, varscan2
- PPP1R3A | c.1407dup p.H470Tfs*2 | Frame Shift Ins (INS) | VAF 138/304 reads (45%) | catalogued as rs770029712; called by mutect2, pindel, varscan2
- PRELID3A | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 331/581 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1348479190; called by muse, mutect2, varscan2
- RETSAT | c.1720G>C p.V574L | Missense Mutation (SNP) | VAF 37/528 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1198176836, COSV99806351; called by muse, mutect2
- RNH1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 367/789 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.605); catalogued as rs1250874456, COSV62250780; called by muse, mutect2, varscan2
- RPS6KA5 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756086272, COSV56225720; called by muse, mutect2, varscan2
- SH3D21 | c.1180G>A p.D394N (on ENST00000453908 / NM_001162530.2; = p.D283N on NM_024676.5) | Missense Mutation (SNP) | VAF 294/655 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs749449765; called by muse, mutect2, varscan2
- SHANK2 | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 57/442 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); catalogued as rs782130683, COSV53600412; called by muse, mutect2, varscan2
- SIPA1L3 | c.1295A>G p.N432S | Missense Mutation (SNP) | VAF 264/533 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769907886; called by muse, mutect2, varscan2
- SPTA1 | c.2248G>T p.A750S | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV63759209; called by muse, mutect2, varscan2
- TNFSF11 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 360/716 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs199558758; called by muse, mutect2
- TRHDE | c.1758A>C p.E586D | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV53838055; called by muse, mutect2, varscan2
- TSC22D4 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 195/377 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV55724512; called by muse, mutect2, varscan2
- UTRN | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.287); catalogued as COSV62335031; called by muse, mutect2, varscan2
- ZIC4 | c.431G>A p.C144Y | Missense Mutation (SNP) | VAF 72/551 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67172788, COSV67174555; called by muse, mutect2, varscan2
- ZNF516 | c.2809G>A p.A937T | Missense Mutation (SNP) | VAF 214/412 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs757514196; called by muse, mutect2, varscan2
- ACTRT1 | c.911C>A p.T304N | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ADGRL4 | c.971A>C p.N324T | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADRA1B | c.636C>G p.F212L | Missense Mutation (SNP) | VAF 116/520 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- AGBL2 | c.1739T>A p.L580H | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ANHX | c.501+1G>T p.X167_splice | Splice Site (SNP) | VAF 70/306 reads (23%) | called by muse, mutect2, varscan2
- AURKB | c.287A>T p.E96V | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- BAZ1B | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 189/395 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BRCA2 | c.4286A>T p.Q1429L | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- BTAF1 | c.2672C>G p.T891R | Missense Mutation (SNP) | VAF 170/329 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CACFD1 | c.143_149del p.F48Sfs*7 | Frame Shift Del (DEL) | VAF 57/377 reads (15%) | called by mutect2, pindel, varscan2
- CCDC38 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH18 | c.1984G>T p.G662* | Nonsense Mutation (SNP) | VAF 58/263 reads (22%) | called by muse, mutect2, varscan2
- CEACAM21 | c.357C>A p.Y119* | Nonsense Mutation (SNP) | VAF 118/517 reads (23%) | called by muse, mutect2, varscan2
- CEACAM21 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 113/514 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP54 | c.5356_5364del p.L1786_Y1788del | In Frame Del (DEL) | VAF 48/289 reads (17%) | called by mutect2, pindel, varscan2
- CHGB | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CMYA5 | c.3051G>T p.E1017D | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.292); called by muse, mutect2
- CNBD1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL5A1 | c.100A>C p.S34R | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.693); called by muse, varscan2
- CPS1 | c.1975C>A p.H659N | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRIM1 | c.1669C>A p.H557N | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTLA4 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 16/520 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- DAAM2 | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK10 | c.4217C>A p.T1406N | Missense Mutation (SNP) | VAF 140/267 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- DTNBP1 | c.62A>T p.K21M | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EPS8L2 | c.1751A>G p.D584G | Missense Mutation (SNP) | VAF 103/388 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ESR1 | c.1080G>A p.W360* | Nonsense Mutation (SNP) | VAF 117/262 reads (45%) | called by muse, mutect2, varscan2
- FAM98A | c.543A>C p.K181N | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FAT3 | c.5609A>C p.N1870T | Missense Mutation (SNP) | VAF 105/399 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.9601T>C p.Y3201H | Missense Mutation (SNP) | VAF 146/146 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, varscan2
- FOXD4L5 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 182/966 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, varscan2
- FRRS1L | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 14/460 reads (3%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); called by muse, mutect2
- GALNT17 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 264/481 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HYDIN | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- IMPDH1 | c.500A>C p.E167A (on ENST00000470772 / NM_001142573.2; = p.E253A on NM_000883.4) | Missense Mutation (SNP) | VAF 170/317 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KLRC1 | c.506T>A p.I169N | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT72 | c.571T>G p.S191A | Missense Mutation (SNP) | VAF 14/476 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.411); called by muse, mutect2
- KRT78 | c.979G>T p.V327F | Missense Mutation (SNP) | VAF 108/398 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- LRRN3 | c.1096C>A p.H366N | Missense Mutation (SNP) | VAF 217/418 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MCF2L2 | c.2202C>A p.Y734* | Nonsense Mutation (SNP) | VAF 68/261 reads (26%) | called by muse, mutect2, varscan2
- MMRN1 | c.2094A>T p.R698S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC6 | c.5665_5666del p.T1889Pfs*21 | Frame Shift Del (DEL) | VAF 234/1498 reads (16%) | called by pindel, varscan2
- MYF6 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 230/444 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- MYO9B | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 73/323 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NFE2L2 | c.1247dup p.H416Qfs*4 | Frame Shift Ins (INS) | VAF 184/472 reads (39%) | called by mutect2, pindel, varscan2
- NKX3-2 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 382/382 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- NME3 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 265/485 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10J5 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- OR10X1 | c.392T>A p.L131H | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2F1 | c.104del p.Y35Lfs*3 | Frame Shift Del (DEL) | VAF 112/533 reads (21%) | called by mutect2, pindel, varscan2
- P3H3 | c.1694G>A p.C565Y | Missense Mutation (SNP) | VAF 211/398 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PCLO | c.3657dup p.L1220Tfs*4 | Frame Shift Ins (INS) | VAF 118/292 reads (40%) | called by mutect2, varscan2
- PLXDC1 | c.117_123del p.T40Gfs*22 | Frame Shift Del (DEL) | VAF 68/310 reads (22%) | called by mutect2, pindel, varscan2
- POR | c.1156_1157del p.T386Qfs*63 | Frame Shift Del (DEL) | VAF 123/716 reads (17%) | called by mutect2, pindel, varscan2
- PPM1K | c.713A>C p.K238T | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.379); called by muse, mutect2
- PRDM14 | c.1084C>G p.L362V | Missense Mutation (SNP) | VAF 78/461 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRPF40A | c.1647_1649del p.L549del | In Frame Del (DEL) | VAF 85/169 reads (50%) | called by mutect2, pindel, varscan2
- RP1L1 | c.1871_1874del p.A624Vfs*58 | Frame Shift Del (DEL) | VAF 49/484 reads (10%) | called by mutect2, pindel, varscan2
- RPL3 | c.346A>G p.R116G | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SEM1 | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SFTPD | c.1121A>C p.E374A | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SH2D3C | c.1620G>C p.K540N (on ENST00000314830 / NM_170600.3; = p.K383N on NM_005489.4) | Missense Mutation (SNP) | VAF 126/493 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SIX3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 221/511 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SNX11 | c.809del p.K270Sfs*8 | Frame Shift Del (DEL) | VAF 48/224 reads (21%) | called by mutect2, pindel, varscan2
- STAT4 | c.1527del p.N511Tfs*50 | Frame Shift Del (DEL) | VAF 38/425 reads (9%) | called by mutect2, pindel
- SYNE2 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 142/289 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM262 | c.242A>G p.K81R (on ENST00000530719 / NM_001282448.1; = p.N79S on NM_001242631.2) | Missense Mutation (SNP) | VAF 113/408 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- TRPC5 | c.545T>A p.V182E | Missense Mutation (SNP) | VAF 135/266 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TTN | c.72658C>T p.H24220Y (on ENST00000591111; = p.H16796Y on NM_003319.4) | Missense Mutation (SNP) | VAF 152/350 reads (43%) | PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TYSND1 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 406/823 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- UHRF1BP1 | c.1392C>G p.S464R | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- USH2A | c.692A>C p.E231A | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- USP25 | c.1000C>A p.H334N | Missense Mutation (SNP) | VAF 85/160 reads (53%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- WDFY3 | c.6607G>C p.V2203L | Missense Mutation (SNP) | VAF 110/110 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- WIZ | c.2725C>A p.P909T (on ENST00000673675 / NM_001371589.1; = p.P172T on NM_021241.3) | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF214 | c.621A>T p.E207D | Missense Mutation (SNP) | VAF 88/412 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF708 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ADAMTS18 | c.1779C>T p.S593= | Silent (SNP) | VAF 205/434 reads (47%) | catalogued as rs559246837, COSV51398793, COSV51423953; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1212C>T p.N404= | Silent (SNP) | VAF 299/632 reads (47%) | catalogued as rs1469979317; called by muse, mutect2, varscan2
- AMY2A | c.1122G>T p.G374= | Silent (SNP) | VAF 48/293 reads (16%) | called by mutect2, varscan2
- ANKUB1 | c.1104C>T p.S368= | Silent (SNP) | VAF 217/492 reads (44%) | catalogued as rs751537489; called by muse, mutect2
- AOC1 | c.198G>A p.K66= | Silent (SNP) | VAF 206/421 reads (49%) | catalogued as COSV62868315; called by mutect2, varscan2
- ARHGEF26 | c.1659T>C p.F553= | Silent (SNP) | VAF 101/211 reads (48%) | called by muse, mutect2, varscan2
- BICRA | c.4038G>A p.P1346= | Silent (SNP) | VAF 270/541 reads (50%) | called by muse, mutect2, varscan2
- BSN | c.1218T>C p.P406= | Silent (SNP) | VAF 131/690 reads (19%) | called by muse, mutect2, varscan2
- CELSR3 | c.1611C>T p.D537= | Silent (SNP) | VAF 268/604 reads (44%) | catalogued as rs1190275035, COSV99374981; called by muse, mutect2, varscan2
- CEP295 | c.3081A>G p.K1027= | Silent (SNP) | VAF 77/292 reads (26%) | called by muse, mutect2, varscan2
- CNTN5 | c.192T>G p.A64= | Silent (SNP) | VAF 89/492 reads (18%) | called by muse, mutect2, varscan2
- COL15A1 | c.21C>T p.N7= | Silent (SNP) | VAF 64/327 reads (20%) | catalogued as rs369351245; called by muse, mutect2, varscan2
- COL9A1 | c.1176C>T p.P392= | Silent (SNP) | VAF 88/347 reads (25%) | called by muse, mutect2, varscan2
- DAGLB | c.1929C>T p.I643= | Silent (SNP) | VAF 207/435 reads (48%) | called by muse, mutect2, varscan2
- DNAH9 | c.381G>A p.A127= | Silent (SNP) | VAF 194/194 reads (100%) | catalogued as rs1484287727; called by muse, mutect2, varscan2
- GBP5 | c.1053G>T p.L351= | Silent (SNP) | VAF 24/314 reads (8%) | called by muse, mutect2
- GPATCH2L | c.426C>T p.S142= | Silent (SNP) | VAF 73/272 reads (27%) | catalogued as rs199736144; called by muse, mutect2, varscan2
- IKZF1 | c.1065G>A p.A355= | Silent (SNP) | VAF 277/552 reads (50%) | called by muse, mutect2, varscan2
- MOS | c.804T>C p.T268= | Silent (SNP) | VAF 90/430 reads (21%) | called by muse, mutect2, varscan2
- MUC2 | c.1134C>T p.P378= | Silent (SNP) | VAF 123/424 reads (29%) | catalogued as COSV100364753; called by muse, mutect2, varscan2
- OBSCN | c.16194G>A p.P5398= | Silent (SNP) | VAF 220/405 reads (54%) | catalogued as rs998955873; called by muse, mutect2, varscan2
- PARP9 | c.510C>A p.A170= | Silent (SNP) | VAF 17/431 reads (4%) | called by muse, mutect2
- PREX2 | c.3852G>A p.A1284= | Silent (SNP) | VAF 192/367 reads (52%) | catalogued as rs150877619, COSV55759958; called by muse, mutect2, varscan2
- RADIL | c.111G>A p.R37= | Silent (SNP) | VAF 217/485 reads (45%) | called by muse, mutect2, varscan2
- RBMXL2 | c.960C>T p.S320= | Silent (SNP) | VAF 251/492 reads (51%) | catalogued as COSV60978749; called by muse, mutect2, varscan2
- RHBDF1 | c.228C>T p.S76= | Silent (SNP) | VAF 150/299 reads (50%) | called by muse, mutect2, varscan2
- RNF31 | c.2064G>T p.R688= | Silent (SNP) | VAF 64/446 reads (14%) | called by muse, mutect2, varscan2
- SEPTIN3 | c.33C>T p.D11= | Silent (SNP) | VAF 91/261 reads (35%) | catalogued as rs746690527; called by muse, mutect2, varscan2
- SETD5 | c.3456T>G p.S1152= | Silent (SNP) | VAF 63/308 reads (20%) | called by muse, mutect2, varscan2
- SIRPB1 | c.387C>T p.D129= | Silent (SNP) | VAF 223/468 reads (48%) | catalogued as rs201140189; called by muse, mutect2, varscan2
- SLITRK2 | c.1456T>C p.L486= | Silent (SNP) | VAF 221/221 reads (100%) | called by muse, mutect2, varscan2
- SLITRK2 | c.2043C>T p.D681= | Silent (SNP) | VAF 260/260 reads (100%) | catalogued as rs182696674, COSV59425016; called by muse, mutect2, varscan2
- SOX11 | c.996G>A p.S332= | Silent (SNP) | VAF 236/533 reads (44%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | c.933G>A p.L311= | Silent (SNP) | VAF 16/236 reads (7%) | catalogued as rs1032601982; called by muse, mutect2
- TBC1D9B | c.3393C>A p.G1131= (on ENST00000356834 / NM_198868.3; = p.G1114= on NM_015043.4) | Silent (SNP) | VAF 243/547 reads (44%) | called by muse, mutect2
- TTBK1 | c.3816G>T p.P1272= | Silent (SNP) | VAF 141/586 reads (24%) | catalogued as rs1309377531; called by muse, mutect2, varscan2
- TTLL10 | c.168C>G p.G56= | Silent (SNP) | VAF 86/536 reads (16%) | called by muse, mutect2, varscan2
- UTRN | c.6834G>A p.Q2278= | Silent (SNP) | VAF 30/247 reads (12%) | called by muse, mutect2, varscan2
- VAT1L | c.87C>T p.G29= | Silent (SNP) | VAF 310/591 reads (52%) | called by muse, mutect2, varscan2
- VWCE | c.453C>T p.C151= | Silent (SNP) | VAF 193/376 reads (51%) | catalogued as rs768199809, COSV57110814, COSV57110878; called by muse, mutect2, varscan2
- ZNF532 | c.1569C>T p.H523= | Silent (SNP) | VAF 182/448 reads (41%) | catalogued as rs542290005; called by muse, mutect2, varscan2
- ZNF729 | c.3432C>A p.S1144= | Silent (SNP) | VAF 43/190 reads (23%) | called by muse, varscan2
- ACIN1 | c.2298-1917G>T | Intron (SNP) | VAF 121/281 reads (43%) | catalogued as rs747401883; called by muse, mutect2, varscan2
- FBLN1 | c.1698-11432C>A | Intron (SNP) | VAF 223/387 reads (58%) | called by muse, mutect2, varscan2
- KLF7 | c.*249A>T | 3'UTR (SNP) | VAF 58/228 reads (25%) | called by muse, mutect2, varscan2
- LINC01116 | n.858G>A | RNA (SNP) | VAF 115/251 reads (46%) | called by mutect2, varscan2
- NHSL2 | chrX:72143404 G>T | 3'Flank (SNP) | VAF 201/201 reads (100%) | called by muse, mutect2, varscan2
- PARD3B | c.2630+120G>A | Intron (SNP) | VAF 174/390 reads (45%) | catalogued as rs745790875; called by muse, mutect2, varscan2
- STARD13 | c.170-18280G>C | Intron (SNP) | VAF 29/395 reads (7%) | called by muse, mutect2
- TTN | c.10360+2424A>T | Intron (SNP) | VAF 147/325 reads (45%) | catalogued as COSV60412283; called by muse, mutect2, varscan2
